Gene-level copy-number profile of tumor specimen TCGA-24-1104-01A from TCGA case TCGA-24-1104, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 56.2 years (20,527 days).
Specimen TCGA-24-1104-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.3f7272d0-dda4-4232-a079-d77f1567d529.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-24-1104-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/aee05d26-4686-4b7f-851c-0b188918b2b0

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 15,393; copy number 3: 3,742; copy number 4: 27,989; copy number 5: 2,436; copy number 6: 8,368; copy number 7: 39; copy number 8: 1,117; copy number 9: 223; copy number 10: 347; copy number 11: 163.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-24-1104-01A-01D-0428-01): tumor purity 0.72, ploidy 1.96, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 733 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:139,003,962–139,357,223, 8 genes, copy number 9 (within-gene range 6–9): PRR23A, MRPS22, PRR23B, PRR23C, RPL7L1P7, BPESC1, PISRT1, AC119740.1.
- chr7:94,278,680–103,989,658, 298 genes, copy number 10 (within-gene range 8–10) (broad region; genes not listed).
- chr7:106,372,251–134,735,129, 427 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
